Gene-level copy-number profile of tumor specimen TCGA-IG-A3Y9-01A from TCGA case TCGA-IG-A3Y9, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 72.1 years (26,330 days).
Specimen TCGA-IG-A3Y9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.873b2990-7be5-439d-8565-9277c1aef149.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A3Y9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/59d4cfde-bc2b-46b7-8b42-0eddabfbf2d2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 3,426; copy number 2: 12,369; copy number 3: 22,545; copy number 4: 11,486; copy number 5: 5,841; copy number 6: 2,742; copy number 7: 27; copy number 8: 1,082; copy number 9: 40; copy number 13: 27; copy number 15: 128; copy number 16: 9; copy number 28: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A3Y9-01A-12D-A246-01): tumor purity 0.27, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:131,493,964–132,648,688, 14 genes (within-gene range 0–2): AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1, AC105443.1, PLXNA4, AC018643.1, AC011625.1.
- chr9:21,638,285–22,029,594, 11 genes (within-gene range 0–4): H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,009,305, 2 genes: AL449423.1, CDKN2B.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,338 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:62,460,940–65,707,226, 27 genes, copy number 7 (within-gene range 3–7): DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr7:70,972–63,060,084, 1,082 genes, copy number 8 (broad region; genes not listed).
- chr11:66,509,079–66,668,374, 13 genes, copy number 13 (within-gene range 3–13): AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF, CCDC87, CCS, RNU4-39P, RBM14, RBM14-RBM4, RBM4.
- chr11:68,891,276–75,018,893, 216 genes, copy number 9–28 (within-gene range 3–28) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,870. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
